Somatic mutation profile of tumor specimen HCM-CSHL-0142-C18-01A (aliquot HCM-CSHL-0142-C18-01A-11D-A77E-36) from HCMI case HCM-CSHL-0142-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: GB; Age at diagnosis: 61.3 years (22,391 days).
Specimen HCM-CSHL-0142-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2704c12a-6c69-45e7-82a3-d3719f6e67a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0142-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0142-C18-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c15f65cf-670f-44c7-ab19-1462636d9cc3

The open-access MAF lists 109 somatic variants for this specimen: 81 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 20, Nonsense Mutation 5, Frame Shift Del 4, RNA 3, Intron 3, 3'UTR 2, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1548+3_1548+4del p.X516_splice | Splice Site (DEL) | VAF 81/233 reads (35%) | catalogued as rs886039510; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ATP1A2 | c.2876C>T p.T959M | Missense Mutation (SNP) | VAF 59/351 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1226796744; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 233/336 reads (69%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 76/611 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.961); catalogued as rs769019873, COSV63241353; called by muse, mutect2, varscan2
- APC | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 42/181 reads (23%) | catalogued as COSV57322620, COSV57331090; called by muse, mutect2, varscan2
- AQP10 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 145/236 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as rs778846975, COSV61474642; called by muse, mutect2, varscan2
- CAPRIN2 | c.2788C>A p.P930T | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as COSV51831061; called by muse, mutect2
- CAPZA3 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs770419225, COSV56851706; called by muse, mutect2, varscan2
- CHST2 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.237); catalogued as COSV100535828; called by muse, mutect2, varscan2
- CNTNAP4 | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs376248782, COSV100268994, COSV56698683; called by muse, mutect2, varscan2
- COL5A2 | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 102/325 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs201486858, COSV66408701; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- COLEC11 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 88/586 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.173); catalogued as rs368184468, COSV52596433; called by muse, mutect2, varscan2
- CSPG4 | c.1958C>T p.T653M | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs371972204; called by muse, mutect2, varscan2
- DCLK1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1228347026; called by muse, mutect2, varscan2
- DNER | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs766950356; called by muse, mutect2, varscan2
- DOCK5 | c.1380G>T p.K460N | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52399504; called by muse, mutect2, varscan2
- DPEP3 | c.1292G>A p.S431N | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99262676; called by muse, mutect2, varscan2
- ELOA2 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 177/594 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs766103603, COSV55304399; called by muse, mutect2, varscan2
- FLG | c.5630G>T p.G1877V | Missense Mutation (SNP) | VAF 131/726 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100910908; called by muse, mutect2, varscan2
- GDPD3 | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.75); catalogued as COSV99531217; called by muse, mutect2, varscan2
- GPRIN2 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1212942786; called by muse, mutect2
- GRIK4 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 246/427 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs199635994, COSV70804948; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 115/690 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1236267082; called by muse, mutect2, varscan2
- HMCN1 | c.10904G>A p.R3635Q | Missense Mutation (SNP) | VAF 78/435 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs777872545, COSV54908505; called by muse, mutect2, varscan2
- KIF1A | c.4028C>T p.A1343V (on ENST00000320389 / NM_001379639.1; = p.A1335V on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 210/541 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs375688061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF2B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457562898, COSV52129186, COSV52132583, COSV52133299; called by muse, mutect2, varscan2
- KLHDC4 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572950700, COSV54507383; called by muse, mutect2
- KMT2D | c.1037G>C p.C346S | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770032317; called by muse, mutect2, varscan2
- KRT1 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 233/536 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs756735090, COSV52868370; called by muse, mutect2, varscan2
- KRT34 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs767269385, COSV67449159; called by muse, mutect2, varscan2
- KRT34 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs754958901; called by muse, mutect2
- LRRC15 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs888813435, COSV61649445; called by muse, mutect2, varscan2
- LRRN4 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 48/495 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV66646337; called by muse, mutect2
- LRRN4 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 210/479 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs770571352; called by muse, mutect2, varscan2
- MED13 | c.5488C>T p.R1830W | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs564327908, COSV67264555; called by muse, mutect2, varscan2
- MGAT3 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 117/510 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1255865821, COSV100361821, COSV57865078; called by muse, varscan2
- MOBP | c.482G>A p.R161H (on ENST00000420739; = p.R185H on NM_001278322.2) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | PolyPhen probably damaging (0.984); catalogued as rs1157650454; called by muse, varscan2
- NLRP2 | c.3040C>T p.R1014W | Missense Mutation (SNP) | VAF 119/695 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs996672212, COSV54756086; called by muse, mutect2, varscan2
- NPBWR1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 148/337 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58696238; called by muse, mutect2, varscan2
- PABPC3 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 82/736 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs760196305, COSV55796443; called by muse, varscan2
- PCDHGB5 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs756430299, COSV53916725; called by muse, mutect2
- PDE8A | c.969C>G p.I323M | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.69); catalogued as rs1468390872; called by muse, mutect2, varscan2
- PPP2R2C | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs776449314, COSV59447500; called by muse, mutect2, varscan2
- RASL12 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs776965372, COSV54982652, COSV99585249; called by muse, mutect2, varscan2
- RIMS2 | c.1061G>A p.R354Q (on ENST00000666250 / NM_001348490.2; = p.R162Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/328 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747383172, COSV51711662; called by muse, mutect2, varscan2
- RTL1 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as rs146372942; called by muse, mutect2, varscan2
- SDK1 | c.6400G>A p.E2134K | Missense Mutation (SNP) | VAF 91/635 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774146423, COSV67354685; called by muse, mutect2, varscan2
- SLAIN1 | c.1268C>T p.P423L (on ENST00000466548; = p.P160L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs760947286, COSV57385949, COSV57388192; called by muse, mutect2, varscan2
- SMARCAD1 | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62775888; called by muse, mutect2, varscan2
- SRRM2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.712); catalogued as rs777411420; called by muse, mutect2, varscan2
- TNR | c.3913C>T p.R1305W | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778628919, COSV54896002, COSV99689299; called by muse, mutect2, varscan2
- UNC45B | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 127/270 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs780354757, COSV52092052; called by muse, mutect2, varscan2
- ZFP82 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 65/162 reads (40%) | catalogued as rs1292048626; called by muse, mutect2, varscan2
- ZNF624 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as rs777042861, COSV60941478; called by muse, mutect2, varscan2
- AGPAT3 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- AKAP11 | c.409A>T p.R137W | Missense Mutation (SNP) | VAF 177/299 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- C12orf56 | c.1013T>G p.L338R (on ENST00000543942 / NM_001170633.2; = p.L178R on NM_001099676.3) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CCNF | c.742_743del p.R248Gfs*33 | Frame Shift Del (DEL) | VAF 214/430 reads (50%) | called by mutect2, pindel, varscan2
- CELSR2 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 78/359 reads (22%) | called by muse, mutect2, varscan2
- CLCN7 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 96/695 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CYSRT1 | c.322G>A p.G108S (on ENST00000409414; = p.G68S on NM_199001.5) | Missense Mutation (SNP) | VAF 82/351 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DAB1 | c.201del p.K67Nfs*21 | Frame Shift Del (DEL) | VAF 84/204 reads (41%) | called by mutect2, pindel, varscan2
- DGKD | c.1966G>A p.D656N (on ENST00000264057 / NM_152879.3; = p.D612N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- DONSON | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FLNB | c.6779A>G p.Y2260C | Missense Mutation (SNP) | VAF 111/246 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- GPATCH8 | c.3025T>G p.S1009A | Missense Mutation (SNP) | VAF 188/385 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HNRNPH1 | c.949_953dup p.H318Qfs*12 | Frame Shift Ins (INS) | VAF 40/175 reads (23%) | called by mutect2, pindel, varscan2
- LRRC4B | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- LTBP2 | c.2279G>T p.S760I | Missense Mutation (SNP) | VAF 169/553 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MAGEC2 | c.151del p.S51Pfs*11 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- MGAM2 | c.2407C>A p.L803M | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL15 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO3B | c.3291C>A p.A1097= | Splice Region (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- NOSTRIN | c.373C>T p.L125F (on ENST00000317647 / NM_001039724.4; = p.L47F on NM_052946.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PTPRM | c.3928A>T p.I1310F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- PXDNL | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 137/458 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPIB | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 171/508 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTBN2 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 138/618 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- TFAP2A | c.130G>A p.A44T (on ENST00000482890; = p.A36T on NM_001032280.3) | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TIFA | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 43/217 reads (20%) | called by mutect2, pindel, varscan2
- ZNF831 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADGRL3 | c.4323G>C p.L1441= (on ENST00000506720 / NM_001322402.2; = p.L1330= on NM_015236.6) | Silent (SNP) | VAF 70/253 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.777G>A p.P259= | Silent (SNP) | VAF 196/347 reads (56%) | catalogued as rs755591407; called by muse, mutect2, varscan2
- AXL | c.2302C>T p.L768= (on ENST00000301178 / NM_021913.5; = p.L759= on NM_001699.6) | Silent (SNP) | VAF 114/321 reads (36%) | catalogued as rs1383571735; called by muse, mutect2, varscan2
- DAAM2 | c.2013G>A p.S671= | Silent (SNP) | VAF 58/302 reads (19%) | catalogued as rs1234127103, COSV51339249, COSV51418823; called by muse, mutect2, varscan2
- FLG2 | c.5478C>T p.H1826= | Silent (SNP) | VAF 88/412 reads (21%) | catalogued as rs557753791, COSV101165793; called by muse, mutect2, varscan2
- GRID1 | c.858G>A p.P286= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as rs571556938, COSV60016101, COSV60054378; called by muse, mutect2, varscan2
- ITPRIP | c.687C>T p.S229= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- JAKMIP1 | c.975C>T p.T325= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as rs559005605, COSV51532136; called by muse, mutect2
- MYO1F | c.1578C>T p.S526= | Silent (SNP) | VAF 91/390 reads (23%) | catalogued as rs773051503; ClinVar: likely benign; called by muse, mutect2, varscan2
- NALCN | c.2850C>T p.I950= | Silent (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- NKX2-4 | c.864G>A p.Q288= | Silent (SNP) | VAF 26/286 reads (9%) | called by muse, mutect2
- OXCT2 | c.120C>T p.A40= | Silent (SNP) | VAF 31/584 reads (5%) | called by muse, mutect2
- PCDHA2 | c.1251C>T p.S417= | Silent (SNP) | VAF 103/440 reads (23%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.6G>A p.A2= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99534587; called by muse, mutect2, varscan2
- PLXDC2 | c.954G>A p.S318= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as rs368106244, COSV65901388; called by muse, mutect2, varscan2
- POTEF | c.3183G>A p.E1061= | Silent (SNP) | VAF 70/502 reads (14%) | catalogued as rs757547875; called by muse, varscan2
- QRFPR | c.156C>T p.G52= | Silent (SNP) | VAF 213/426 reads (50%) | called by muse, mutect2, varscan2
- SLC12A5 | c.387G>A p.P129= (on ENST00000454036 / NM_001134771.2; = p.P106= on NM_020708.5) | Silent (SNP) | VAF 78/449 reads (17%) | catalogued as rs200144342, COSV99715580; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLITRK6 | c.2076T>C p.S692= | Silent (SNP) | VAF 61/440 reads (14%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.57C>T p.G19= | Silent (SNP) | VAF 115/506 reads (23%) | catalogued as rs199622201, COSV60978351; called by muse, mutect2, varscan2
- AC244258.1 | n.524C>T | RNA (SNP) | VAF 28/163 reads (17%) | catalogued as rs9885751; called by muse, mutect2, varscan2
- AP1S3 | c.*39_*42del | 3'UTR (DEL) | VAF 6/42 reads (14%) | catalogued as rs200257231; called by pindel, varscan2
- ARPP19P1 | n.60_67del | RNA (DEL) | VAF 64/313 reads (20%) | called by mutect2, pindel, varscan2
- GALNT9 | c.1077+182C>G | Intron (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- MLIP | c.613-10871G>A | Intron (SNP) | VAF 124/351 reads (35%) | catalogued as rs763119133; called by muse, mutect2, varscan2
- OR1F2P | n.434C>T | RNA (SNP) | VAF 20/408 reads (5%) | catalogued as rs1042462830; called by muse, mutect2
- PAF1 | c.*55T>G | 3'UTR (SNP) | VAF 20/114 reads (18%) | called by muse, varscan2
- TATDN1 | c.593+358C>T | Intron (SNP) | VAF 11/141 reads (8%) | catalogued as rs762957204; called by muse, mutect2
